Surgical pathology report (de-identified scan), TCGA case TCGA-29-1705, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1705-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]
[REDACTED]
Surg Path

CGA-29-1705

CLINICAL HISTORY:

Malignant neoplasm ovary = 183.0

GROSS EXAMINATION:

A. "Omentum (AF1)", received fresh for frozen section. Received is an aggregate of omentum measuring 16 x 10 x 3 cm. The largest piece measures 12.5 x 6 x 3 cm. All pieces are grossly involved by tumor, with minimal residual normal adipose tissue. A representative section is frozen as AF1, and the frozen section remnant is submitted in block A1. Additional representative sections are submitted in blocks A2-A3.

B. "Right tube and right ovary", received fresh and placed in formalin. Received is a 24.2 gram, 5 x 3.7 x 1.7 cm ovary with attached fimbriated tube. The ovary measures 3.9 x 3.7 x 1.7 cm, and the attached tube is 4 cm long, with a diameter of 0.8 cm. The external surface of the ovary is notable for multiple small tan, papillary growths (inked blue). Sectioning reveals a white nodule measuring 1.7 cm in greatest dimension within the ovary. The attached fallopian tube is remarkable for a 0.6 cm paratubal cyst. Representative sections are submitted in blocks B1-B5, with tube in block B5.

C. "Left tube and left ovary", received fresh and placed in formalin. Received is a 26.8 gram, 4.9 x 4.5 x 1.6 cm specimen consisting of ovary and adjacent adherent fimbriated tube (0.7 cm in diameter). The surface of the ovary contains multiple tan, papillary structures. Also noted is a 1.9 cm serous-filled cyst. The involved surface of the ovary is inked blue. Sectioning reveals solid and cystic areas within the ovary. The solid area measures 2.8 cm in maximum dimension, and appears to merge with the cystic area. The cyst is grossly filled with tan, papillary excrescences. Only a short length of tube is visible, but it is grossly unremarkable. Representative sections of ovary are in blocks C1-C4, and sections of the serous-filled cyst and tube are submitted in block C5.

D. "Transverse colon", received fresh and placed in formalin. Received is a 6.5 cm segment of large bowel (8 cm circumference) with attached pericolic fat. The attached fat is grossly involved by tumor, and appears very fibrotic and hemorrhagic. The involved fat measures 10.5 x 6.8 x 2 cm. Some residual yellow, lobulated adipose tissue is still present. The serosa contains a 0.3 cm firm, white, pedunculated nodule. Diffuse serosal studding is not noted. The bowel mucosa is edematous but otherwise grossly unremarkable, with a normal folding pattern.

BLOCK SUMMARY:

D1- bowel with involved pericolic fat.
D2- representative section of tumor.
D3- serosal nodule.
D4- representative section of bowel.

[REDACTED]

INTRA OPERATIVE CONSULTATION:

A. "Omentum": AF1- papillary serous carcinoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Bilateral salpingo-oophorectomy, omentectomy, partial colectomy.

[REDACTED]

[page 2 of 2]
PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "OMENTUM" (OMENECTOMY):

OMENTUM WITH EXTENSIVE INVOLVEMENT BY PAPILLARY SEROUS ADENOCARCINOMA.
SIZE OF METASTASIS: GREATER THAN 2 CM.

B. "RIGHT TUBE AND RIGHT OVARY" (SALPINGO-OOPHORECTOMY):

OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA.
FIGO GRADE: 2 OF 3.
TUMOR SIZE: APPROXIMATELY 1.7 CM.
SURFACE INVOLVEMENT: PRESENT.
FALLOPIAN TUBE: NO EVIDENCE OF MALIGNANCY.

TCGA-29-1705

C. "LEFT TUBE AND LEFT OVARY" (SALPINGO OOPHORECTOMY):

OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA.
FIGO GRADE: 2 OF 3.
TUMOR SIZE: APPROXIMATELY 2.8 CM.
SURFACE INVOLVEMENT: PRESENT.
FALLOPIAN TUBE: POSITIVE FOR PAPILLARY SEROUS ADENOCARCINOMA.

D. "TRANSVERSE COLON" (PARTIAL COLECTOMY):

SEGMENT OF COLON WITH PAPILLARY SEROUS ADENOCARCINOMA (10.5 CM).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file b83af690-f329-48d2-9ca6-c1a9db4f68b5 (TCGA-29-1705.E7A899E9-2C61-4BDA-874C-0F1B456E5DFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).